Somatic mutation profile of tumor specimen 0DS299 from CCDI case PBCFIZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 11.9 years (4,340 days).
Specimen 0DS299: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20591a62-313b-494d-a8fc-7c033ce49ee0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS29Q (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3bedd683-e533-4c6a-aa71-7f800f5e53e0

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Missense Mutation 2, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY9 | c.2757G>A p.M919I | Missense Mutation (SNP) | VAF 62/618 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV99569440; called by muse, mutect2
- DTX1 | c.1424A>G p.Y475C | Missense Mutation (SNP) | VAF 77/622 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ACCSL | c.81C>T p.T27= | Silent (SNP) | VAF 99/785 reads (13%) | catalogued as COSV101122137; called by muse, mutect2, varscan2
- PCDHB12 | c.1402C>T p.L468= | Silent (SNP) | VAF 36/321 reads (11%) | catalogued as COSV99506983; called by muse, mutect2, varscan2
- CD70 | chr19:6583312 G>A | 3'Flank (SNP) | VAF 69/605 reads (11%) | catalogued as rs887844162; called by muse, mutect2
- RBBP4 | c.-71C>G | 5'UTR (SNP) | VAF 36/220 reads (16%) | called by muse, mutect2, varscan2
